Gene-level copy-number profile of tumor specimen TCGA-HZ-A4BH-01A from TCGA case TCGA-HZ-A4BH, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 75.7 years (27,637 days).
Specimen TCGA-HZ-A4BH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.78019f1b-acce-4c2c-bee5-ea9679a7808d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HZ-A4BH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1fa5a21a-f80b-4534-9ba3-2be5963b2d45

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 11,543; copy number 2: 43,150; copy number 3: 4,260; copy number 4: 269; copy number 5: 216; copy number 6: 86; copy number 7: 249; copy number 8: 3; copy number 9: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HZ-A4BH-01A-11D-A26H-01): tumor purity 0.32, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:27,935,523–30,695,869, 35 genes (within-gene range 0–7): AC008011.1, PTHLH, AC008011.2, CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1, AC022081.1, AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1, TMTC1, AC009320.1, RPL21P99, AC023511.3, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1, AC026371.1, IPO8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 555 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:55,346,242–56,328,625, 21 genes, copy number 5 (within-gene range 3–5): SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135, CRACD, RNA5SP161.
- chr4:56,410,516–57,110,385, 21 genes, copy number 7 (within-gene range 3–7): AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7.
- chr7:23,105,758–23,311,729, 7 genes, copy number 6 (within-gene range 2–6): KLHL7, AK3P3, NUP42, AC005082.2, AC005082.1, GPNMB, MALSU1.
- chr7:23,365,618–23,365,976, 1 gene, copy number 6: AC021876.1.
- chr7:36,512,941–36,724,549, 1 gene, copy number 7 (within-gene range 3–7): AOAH.
- chr7:36,734,004–36,734,535, 1 gene, copy number 7: AC007349.4.
- chr7:47,252,139–47,629,893, 3 genes, copy number 6 (within-gene range 2–6): AC087175.1, TNS3, LINC01447.
- chr7:96,118,647–96,709,891, 9 genes, copy number 5 (within-gene range 4–5): AC002540.1, SLC25A13, MIR591, AC096775.1, AC084368.1, RNU6-532P, RNU6-364P, RNU7-188P, SEM1.
- chr7:98,794,718–102,283,958, 159 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr11:41,122,907–41,123,012, 1 gene, copy number 9: RNU6-365P.
- chr12:30,696,121–32,007,435, 53 genes, copy number 7: AC012673.1, CAPRIN2, AC010198.1, LINC00941, AC010198.2, PPIAP44, TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1.
- chr17:38,765,689–39,747,291, 47 genes, copy number 6: PIP4K2B, CWC25, MIR4727, C17orf98, RPL23, SNORA21B, SNORA21, AC110749.1, LASP1, AC006441.1, MIR6779, AC006441.3, LINC00672, FBXO47, AC006441.2, AC006441.4, AC006441.5, LINC02079, LRRC37A11P, AC091178.1, RDM1P5, PLXDC1, AC091178.2, ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr17:53,353,427–53,354,134, 1 gene, copy number 7: AC005341.1.
- chr17:54,702,936–54,771,277, 3 genes, copy number 8: AC005951.1, ARL2BPP8, RN7SKP14.
- chr17:70,628,917–70,779,230, 2 genes, copy number 5: AC005771.1, AC007423.1.
- chr17:73,737,854–73,836,019, 4 genes, copy number 7: AC125421.1, LINC00469, LINC02092, AC125421.2.
- chr19:37,907,208–38,208,369, 1 gene, copy number 6 (within-gene range 2–6): SIPA1L3.
- chr19:38,108,500–38,636,955, 27 genes, copy number 6: AC011465.1, AC011479.3, AC011479.2, RN7SL663P, DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33, KCNK6, CATSPERG, AC005625.1, PSMD8, GGN, AC005789.1, SPRED3, FAM98C, RASGRP4, RYR1, AC067969.2, AC067969.1, MAP4K1, AC008649.1, EIF3K.
- chr19:42,821,863–46,392,981, 193 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,157. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
